CCDI case PBBSZS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/9b785333-7358-4aaa-9ae5-58b67a5cbe7e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.2 years (1,522 days).

Biospecimens (3 samples)
- Sample 0DG5A6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG5AE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG5AH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
